Gene-level copy-number profile of tumor specimen TCGA-BA-6868-01B from TCGA case TCGA-BA-6868, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 53.7 years (19,608 days).
Specimen TCGA-BA-6868-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.ae5a8519-03d4-4427-bf49-d012fdb361be.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-6868-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d7a7d9b7-4e89-4b4e-bca5-5eb78583ee94

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 451; copy number 2: 9,157; copy number 3: 15,183; copy number 4: 25,883; copy number 5: 3,734; copy number 6: 3,018; copy number 7: 945; copy number 8: 541; copy number 9: 370; copy number 10: 65; copy number 11: 211; copy number 12: 16; copy number 13: 12; copy number 14: 68; copy number 15: 9; copy number 16: 22; copy number 18: 2; copy number 19: 6; copy number 20: 2; copy number 27: 64; copy number 29: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-6868-01B-12D-1910-01): tumor purity 0.66, ploidy 3.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:63,957,874–63,981,043, 2 genes (within-gene range 0–2): HTR1A, AC122707.1.
- chr5:151,504,093–151,568,944, 1 gene (within-gene range 0–4): FAT2.
- chr5:151,595,264–151,686,975, 3 genes (within-gene range 0–4): AC011374.3, AC011374.1, SPARC.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr13:55,535,697–55,583,524, 1 gene (within-gene range 0–4): AL354821.1.
- chr13:89,991,831–92,873,682, 30 genes (within-gene range 0–4): PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 865 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:188,990,715–189,002,075, 1 gene, copy number 10: AC122138.1.
- chr6:53,929,982–54,266,280, 1 gene, copy number 12 (within-gene range 2–12): MLIP.
- chr6:53,978,549–54,079,726, 1 gene, copy number 12 (within-gene range 2–12): MLIP-AS1.
- chr6:54,190,206–54,485,850, 4 genes, copy number 12: AL359380.1, TINAG, TINAG-AS1, CLNS1AP1.
- chr6:165,718,235–170,738,536, 127 genes, copy number 9 (broad region; genes not listed).
- chr7:92,604,921–92,836,573, 1 gene, copy number 10 (within-gene range 4–10): CDK6.
- chr7:92,701,708–93,226,469, 6 genes, copy number 10: RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2.
- chr7:96,118,647–100,092,187, 105 genes, copy number 11–15 (broad region; genes not listed).
- chr7:100,093,560–100,094,074, 3 genes, copy number 11: MIR25, MIR93, MIR106B.
- chr7:102,699,228–105,600,875, 52 genes, copy number 9–27: AC105052.5, FAM185A, AC105052.2, FBXL13, RNU6-1136P, RN7SKP198, LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86, ORC5, LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2.
- chr7:110,590,082–110,592,204, 1 gene, copy number 10: AC073326.2.
- chr8:37,421,341–39,580,134, 68 genes, copy number 14 (within-gene range 6–14) (broad region; genes not listed).
- chr8:122,414,332–138,497,261, 227 genes, copy number 9–10 (broad region; genes not listed).
- chr11:12,030,875–15,082,342, 55 genes, copy number 10–12 (within-gene range 5–12): LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA, AC009806.1, AC107881.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P.
- chr11:70,078,302–70,436,584, 14 genes, copy number 29 (within-gene range 5–29): ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 18–29: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr11:72,685,069–72,793,599, 1 gene, copy number 13 (within-gene range 7–13): ARAP1.
- chr11:72,689,650–72,843,674, 8 genes, copy number 13 (within-gene range 7–13): AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2.
- chr11:72,869,544–72,869,650, 1 gene, copy number 13: RNU6-672P.
- chr11:99,020,949–104,252,651, 69 genes, copy number 19–27 (within-gene range 3–27) (broad region; genes not listed).
- chr16:46,469,341–49,275,579, 70 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr18:34,493,290–34,891,844, 1 gene, copy number 11 (within-gene range 6–11): DTNA.
- chr18:34,737,795–36,829,216, 41 genes, copy number 11 (within-gene range 7–11): AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1, TPGS2.
- chr19:29,606,283–29,675,477, 2 genes, copy number 13: POP4, PLEKHF1.

Autosomal genes at a single copy (total copy number 1): 450. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
